CCDI case PBBRUK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3d264873-8c40-4209-befa-41b0b510163f

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Astroblastoma: ICD-O-3 morphology code: 9430/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.5 years (3,113 days).

Biospecimens (3 samples)
- Sample 0DF5CY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DF5CZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DF5D8: Tissue type: Tumor; Specimen type: Solid Tissue.
